Gene-level copy-number profile of tumor specimen TCGA-4R-AA8I-01A from TCGA case TCGA-4R-AA8I, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 66.5 years (24,279 days).
Specimen TCGA-4R-AA8I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.dd651db9-eb27-448d-bf2f-d0d74d428276.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-4R-AA8I-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/83070789-2be3-4375-8d2d-ac48e7d92158

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 7,602; copy number 2: 50,503; copy number 3: 1,456; copy number 4: 44; copy number 5: 8; copy number 6: 22; copy number 7: 159; copy number 8: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-4R-AA8I-01A-11D-A381-01): tumor purity 0.85, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:142,789–445,939, 10 genes: DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3, AC141424.1, C17orf97, RFLNB.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 199 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:34,018,643–34,773,857, 22 genes, copy number 6 (within-gene range 3–6): GRM4, KRT18P9, CYCSP55, HMGA1, MIR6835, SMIM29, AL354740.1, RPL35P2, NUDT3, RPS10-NUDT3, RPS10, PACSIN1, SPDEF, IFITM3P3, ILRUN, RPL7P25, RN7SL200P, AL031577.1, AL451165.2, AL451165.1, AL139100.1, SNRPC.
- chr6:38,168,451–38,640,148, 1 gene, copy number 5 (within-gene range 1–5): BTBD9.
- chr6:38,481,692–38,715,217, 5 genes, copy number 5: BTBD9-AS1, Y_RNA, AL079341.1, GLO1, AL391415.1.
- chr6:38,744,086–38,764,694, 2 genes, copy number 5: RN7SL465P, AL035555.2.
- chr6:39,329,990–44,830,188, 168 genes, copy number 7–8 (within-gene range 4–8) (broad region; genes not listed).
- chr6:44,898,711–44,899,295, 1 gene, copy number 7: NUDT19P4.

Autosomal genes at a single copy (total copy number 1): 5,220. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
